Somatic mutation profile of tumor specimen ALCH-B06J-TTP1-A (aliquot ALCH-B06J-TTP1-A-2-0-D-A680-36) from ALCHEMIST case ALCH-B06J, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 51.8 years (18,903 days).
Specimen ALCH-B06J-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94e16843-b043-4901-834f-ebd1aab79a3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B06J-NB1-A (Blood Derived Normal), aliquot ALCH-B06J-NB1-A-1-0-D-A680-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e5070ac-6298-44ac-b465-e8b4583778d4

The open-access MAF lists 318 somatic variants for this specimen: 222 protein-altering or splice-affecting, 60 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 187, Silent 60, Intron 17, Nonsense Mutation 13, Frame Shift Del 9, RNA 8, Frame Shift Ins 6, Splice Site 5, 5'UTR 4, 3'UTR 3, 5'Flank 3, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLRN1 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 25/603 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.704); catalogued as rs374390376, CM115178, COSV58996481; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 172/539 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- STK11 | c.924G>C p.W308C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057520042, CM1313845, CM1314422, CM981871, COSV58821324, COSV58824598; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 33/118 reads (28%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1132C>A p.P378T | Missense Mutation (SNP) | VAF 16/316 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1438201765; called by muse, mutect2
- ACP7 | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.005); catalogued as COSV58701142; called by muse, mutect2, varscan2
- ACVRL1 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 52/412 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs779287554, CX139316; called by muse, mutect2, varscan2
- ADNP2 | c.2117A>G p.N706S | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs892223872; called by muse, mutect2, varscan2
- ARPP21 | c.2349C>A p.H783Q | Missense Mutation (SNP) | VAF 61/374 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.104); catalogued as rs777730528; called by muse, mutect2, varscan2
- AUTS2 | c.2965G>T p.D989Y | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs377538146; called by muse, mutect2, varscan2
- BRDT | c.1229A>T p.N410I | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as COSV62864379; called by muse, mutect2, varscan2
- BUB1B | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 149/678 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV104381789; called by muse, mutect2, varscan2
- C6orf118 | c.804C>A p.H268Q | Missense Mutation (SNP) | VAF 64/242 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs535750180; called by muse, mutect2, varscan2
- CDH10 | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 70/385 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV52599728; called by muse, mutect2, varscan2
- CENPJ | c.3196G>T p.E1066* | Nonsense Mutation (SNP) | VAF 92/336 reads (27%) | catalogued as COSV67883975; called by muse, mutect2, varscan2
- CFC1 | c.205G>T p.G69W | Missense Mutation (SNP) | VAF 47/327 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV52090677; called by muse, mutect2, varscan2
- CYP27A1 | c.11T>C p.L4P | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.462); catalogued as rs868195486, CD016076; called by muse, mutect2, varscan2
- DOCK4 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 96/463 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as COSV70314638; called by muse, mutect2, varscan2
- DUOX1 | c.1664A>G p.N555S | Missense Mutation (SNP) | VAF 97/428 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs144822779; called by muse, mutect2, varscan2
- EGFL6 | c.113C>A p.P38H | Missense Mutation (SNP) | VAF 74/336 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV63632797; called by muse, varscan2
- EPHA7 | c.408G>C p.R136S | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.573); catalogued as COSV65168457; called by muse, mutect2, varscan2
- FAM135B | c.1665C>A p.D555E | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as COSV52753154; called by muse, mutect2, varscan2
- FAM160A2 | c.491G>T p.R164L | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV99791971; called by muse, mutect2, varscan2
- GABRQ | c.1840C>T p.L614F | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100941246; called by muse, mutect2, varscan2
- HNF1A | c.812G>T p.R271L | Missense Mutation (SNP) | VAF 80/422 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as CM023589, COSV57465633, COSV99982960; called by muse, varscan2
- HSPA8 | c.1024C>A p.R342S | Missense Mutation (SNP) | VAF 86/351 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV99914471; called by muse, mutect2, varscan2
- IFI44 | c.1002G>T p.L334F | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); catalogued as COSV100877293; called by muse, mutect2
- IGF2BP2 | c.1098G>T p.L366F | Missense Mutation (SNP) | VAF 66/329 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60482985, COSV60485474; called by muse, mutect2, varscan2
- KCNC2 | c.1149G>T p.L383F | Missense Mutation (SNP) | VAF 79/371 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.223); catalogued as COSV100128699; called by muse, mutect2, varscan2
- KRT2 | c.922C>A p.Q308K | Missense Mutation (SNP) | VAF 85/550 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.173); catalogued as COSV100548400; called by muse, mutect2, varscan2
- KRTAP5-4 | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs749631730; called by muse, mutect2, varscan2
- LAMB4 | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 88/389 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV52728386; called by muse, mutect2, varscan2
- MAGEL2 | c.2393C>A p.P798H | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as COSV58569318; called by muse, mutect2, varscan2
- MAP2 | c.234G>T p.E78D | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.578); catalogued as COSV52308226; called by muse, mutect2
- MS4A4E | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.578); catalogued as rs543410624; called by muse, mutect2, varscan2
- MXRA5 | c.8318C>A p.S2773* | Nonsense Mutation (SNP) | VAF 55/236 reads (23%) | catalogued as COSV54237231; called by muse, mutect2, varscan2
- NKTR | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 43/520 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1559578682, COSV51773596; called by muse, mutect2
- NLGN4X | c.2362G>T p.G788W | Missense Mutation (SNP) | VAF 92/454 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52039786, COSV99323267; called by muse, mutect2
- NYAP1 | c.879C>A p.H293Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs748465487, COSV100278424; called by mutect2, varscan2
- OR10AG1 | c.489C>A p.N163K | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as COSV56635616; called by muse, mutect2, varscan2
- OR11L1 | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 85/264 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV63313957, COSV63315850; called by muse, mutect2
- OR8H1 | c.886G>T p.V296F | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57294275; called by muse, mutect2, varscan2
- PCDH10 | c.2330C>A p.A777E | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.573); catalogued as rs750744037, COSV99994882; called by muse, mutect2, varscan2
- PCDHGB6 | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 74/288 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.344); catalogued as rs753753955, COSV53931329; called by muse, mutect2, varscan2
- PCNX2 | c.5207G>T p.R1736L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99269447; called by muse, mutect2, varscan2
- PKD1L2 | c.2651C>A p.T884K | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as rs374090117; called by muse, mutect2, varscan2
- POF1B | c.1025T>A p.L342H | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53133424; called by muse, mutect2, varscan2
- PRDM9 | c.631T>G p.F211V | Missense Mutation (SNP) | VAF 26/442 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV57003742; called by muse, mutect2
- PSG11 | c.257G>C p.G86A | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.314); catalogued as rs376411110; called by muse, mutect2, varscan2
- PTPRT | c.247G>T p.A83S | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.464); catalogued as COSV62010701; called by muse, mutect2, varscan2
- REG1A | c.325C>A p.R109S | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0.261); catalogued as COSV52070715; called by muse, mutect2, varscan2
- RIMS2 | c.1412G>A p.R471Q (on ENST00000666250 / NM_001348490.2; = p.R279Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 120/573 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51661684, COSV51728533; called by mutect2, varscan2
- RPL22L1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 20/306 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs778606198; called by muse, mutect2
- RYR3 | c.10970G>T p.G3657V (on ENST00000389232; = p.G3658V on NM_001036.6) | Missense Mutation (SNP) | VAF 100/402 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV66808554; called by muse, mutect2, varscan2
- SASH1 | c.1669G>T p.G557W | Missense Mutation (SNP) | VAF 67/275 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66559322; called by muse, mutect2, varscan2
- SETD1A | c.4712G>T p.R1571L | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV52681301; called by muse, mutect2, varscan2
- SLC28A2 | c.1076C>A p.A359E | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs991248364, COSV61664185; called by muse, mutect2, varscan2
- SLC8A1 | c.2384C>T p.T795I | Missense Mutation (SNP) | VAF 104/445 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60479313; called by muse, mutect2, varscan2
- SLITRK3 | c.2233C>A p.H745N | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.528); catalogued as rs778293176; called by muse, mutect2, varscan2
- SMR3B | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as COSV59229436; called by muse, mutect2, varscan2
- STAB2 | c.3386C>T p.P1129L | Missense Mutation (SNP) | VAF 60/213 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101186391; called by muse, mutect2, varscan2
- TAS2R1 | c.245G>T p.C82F | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1413724577, COSV66778267; called by muse, mutect2, varscan2
- TCERG1L | c.368C>A p.S123Y | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.135); catalogued as COSV64059518; called by muse, mutect2, varscan2
- TLR4 | c.1697A>T p.H566L (on ENST00000355622 / NM_138554.5; = p.H526L on NM_003266.4) | Missense Mutation (SNP) | VAF 32/273 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100842905, COSV62922743; called by muse, mutect2, varscan2
- TMEM269 | c.152T>C p.I51T (on ENST00000536543; = p.I9T on NM_001354602.1) | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV70105672; called by muse, mutect2
- TSPAN11 | c.403G>T p.G135W | Missense Mutation (SNP) | VAF 80/338 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV53819185; called by muse, mutect2, varscan2
- UNC79 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 31/261 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs751997272; called by muse, mutect2, varscan2
- USP27X | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 37/566 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1440930176; called by muse, mutect2
- VIL1 | c.1165C>G p.Q389E | Missense Mutation (SNP) | VAF 66/317 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV50285437; called by muse, mutect2, varscan2
- VPS13B | c.5326A>G p.I1776V | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs757833793; called by muse, mutect2, varscan2
- WDR1 | c.676G>T p.A226S (on ENST00000382452; = p.A86S on NM_005112.5) | Missense Mutation (SNP) | VAF 104/439 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV101221171; called by muse, mutect2, varscan2
- ZBTB39 | c.2000G>A p.G667E | Missense Mutation (SNP) | VAF 50/267 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1411159164; called by muse, mutect2, varscan2
- ZFHX4 | c.1372G>T p.G458W | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV51443573; called by muse, mutect2, varscan2
- ZNF831 | c.1187G>T p.G396V | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as rs1326566063; called by muse, mutect2, varscan2
- ZNF844 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760052946; called by muse, mutect2, varscan2
- ZXDC | c.1828G>T p.G610C | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60447777; called by muse, mutect2, varscan2
- ABCB1 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 101/375 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ABCG4 | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACSM3 | c.1218T>A p.D406E | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ACTR5 | c.1043A>T p.E348V | Missense Mutation (SNP) | VAF 83/254 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS10 | c.2385T>A p.N795K | Missense Mutation (SNP) | VAF 92/296 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS6 | c.901del p.R301Afs*2 | Frame Shift Del (DEL) | VAF 57/352 reads (16%) | called by mutect2, pindel, varscan2
- ADGRA3 | c.578G>T p.C193F | Missense Mutation (SNP) | VAF 47/258 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRB3 | c.4465G>C p.D1489H | Missense Mutation (SNP) | VAF 89/429 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- ADGRL4 | c.1130C>A p.P377H | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- ANKRD34B | c.162dup p.H55Tfs*9 | Frame Shift Ins (INS) | VAF 54/220 reads (25%) | called by mutect2, pindel, varscan2
- APLP1 | c.693_702del p.W231* | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- ARMC3 | c.883G>T p.A295S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- BCORL1 | c.2205C>A p.N735K | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- BDP1 | c.5533_5546del p.G1845Sfs*3 | Frame Shift Del (DEL) | VAF 66/396 reads (17%) | called by mutect2, pindel
- BOLL | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 51/219 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- BTF3 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- C11orf65 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 91/419 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CACNA1E | c.1713G>T p.L571F | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- CCDC114 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 17/185 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); called by muse, mutect2
- CCDC168 | c.13213G>T p.E4405* | Nonsense Mutation (SNP) | VAF 51/339 reads (15%) | called by muse, mutect2, varscan2
- CDH10 | c.127del p.R43Gfs*33 | Frame Shift Del (DEL) | VAF 144/640 reads (23%) | called by mutect2, pindel, varscan2
- CELSR1 | c.1180G>T p.G394W | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by mutect2, varscan2
- CHD2 | c.4647dup p.K1550* | Frame Shift Ins (INS) | VAF 78/430 reads (18%) | called by pindel, varscan2
- CNST | c.1954G>C p.D652H | Missense Mutation (SNP) | VAF 35/253 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CNTN3 | c.2498del p.G833Dfs*23 | Frame Shift Del (DEL) | VAF 50/189 reads (26%) | called by mutect2, pindel, varscan2
- COL14A1 | c.3031C>G p.R1011G | Missense Mutation (SNP) | VAF 106/449 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL18A1 | c.1825G>T p.G609C (on ENST00000359759 / NM_130444.3; = p.G374C on NM_030582.4) | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2
- COL2A1 | c.3502C>G p.P1168A | Missense Mutation (SNP) | VAF 59/240 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- COL5A1 | c.4591G>C p.G1531R | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPEB2 | c.2918G>A p.G973D | Missense Mutation (SNP) | VAF 40/313 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- CPXM1 | c.1599C>A p.S533R | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- CRBN | c.86A>G p.D29G | Missense Mutation (SNP) | VAF 41/540 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.055); called by muse, mutect2
- CTH | c.1201_1202delinsT p.S401Lfs*26 | Frame Shift Del (DEL) | VAF 47/325 reads (14%) | called by pindel, varscan2*
- DACH1 | c.2269del p.M757Cfs*13 (on ENST00000619232 / NM_001366712.1; = p.M503Cfs*13 on NM_004392.6) | Frame Shift Del (DEL) | VAF 81/445 reads (18%) | called by mutect2, pindel, varscan2
- DOT1L | c.788G>A p.G263D | Missense Mutation (SNP) | VAF 19/279 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EDIL3 | c.895C>A p.Q299K | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ENC1 | c.1037G>C p.G346A | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- EPHA8 | c.600C>A p.Y200* | Nonsense Mutation (SNP) | VAF 36/158 reads (23%) | called by muse, mutect2, varscan2
- ESCO1 | c.427G>T p.G143C | Missense Mutation (SNP) | VAF 128/773 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- ETNPPL | c.535A>G p.R179G | Missense Mutation (SNP) | VAF 82/325 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- FAT2 | c.3464C>A p.S1155Y | Missense Mutation (SNP) | VAF 55/239 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSIP2 | c.7418G>T p.G2473V | Missense Mutation (SNP) | VAF 75/268 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- G6PC2 | c.249G>T p.W83C | Missense Mutation (SNP) | VAF 106/453 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GFRA2 | c.592C>A p.R198S | Missense Mutation (SNP) | VAF 77/337 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- GLYATL3 | c.715C>A p.Q239K | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.109); called by muse, varscan2
- GPR26 | c.91C>A p.L31M | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- GRAP | c.608G>T p.R203L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.187); called by muse, mutect2
- GRIA4 | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 124/477 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- GRIK2 | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.127); called by muse, varscan2
- HECTD4 | c.8462G>C p.W2821S | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HFM1 | c.3979G>C p.V1327L | Missense Mutation (SNP) | VAF 78/283 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- HYDIN | c.8035G>A p.G2679R | Missense Mutation (SNP) | VAF 66/247 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- INSYN2B | c.806C>A p.P269Q | Missense Mutation (SNP) | VAF 54/263 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- INTS9 | c.1881G>T p.Q627H | Missense Mutation (SNP) | VAF 125/657 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ITGB7 | c.1396C>A p.L466M | Missense Mutation (SNP) | VAF 63/234 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ITPKB | c.408dup p.E137Rfs*15 | Frame Shift Ins (INS) | VAF 77/229 reads (34%) | called by mutect2, pindel, varscan2
- KCNT1 | c.1687T>G p.Y563D (on ENST00000488444; = p.Y582D on NM_020822.3) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.041); called by muse, varscan2
- KIF1A | c.751G>T p.G251W | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KREMEN2 | c.1324dup p.A442Gfs*81 (on ENST00000303746 / NM_172229.3; = p.R416Afs*22 on NM_024507.4) | Frame Shift Ins (INS) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- KRT74 | c.619G>T p.G207W | Missense Mutation (SNP) | VAF 119/460 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP19-4 | c.96C>A p.F32L | Missense Mutation (SNP) | VAF 44/374 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- L1CAM | c.546C>A p.D182E | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LGALS16 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 143/398 reads (36%) | called by muse, mutect2, varscan2
- LRRC10 | c.255C>A p.N85K | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LUM | c.143C>A p.P48Q | Missense Mutation (SNP) | VAF 54/292 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEE1 | c.2830G>T p.A944S | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.121); called by muse, mutect2
- MAP3K7 | c.105G>T p.E35D | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- MARCHF10 | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 78/401 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- MED26 | c.1340G>A p.S447N | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MKS1 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 98/516 reads (19%) | called by muse, mutect2, varscan2
- MREG | c.290dup p.R98Afs*25 | Frame Shift Ins (INS) | VAF 108/523 reads (21%) | called by mutect2, pindel, varscan2
- MSX1 | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MT1G | c.134G>A p.C45Y (on ENST00000379811 / NM_001301267.2; = p.C44Y on NM_005950.3) | Missense Mutation (SNP) | VAF 13/303 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MTOR | c.4601G>T p.C1534F | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MUC16 | c.13207C>A p.L4403I | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- N4BP2 | c.4693G>T p.G1565W | Missense Mutation (SNP) | VAF 58/347 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NECTIN2 | c.17C>A p.A6D | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, varscan2
- NEK10 | c.3252G>T p.K1084N | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NKX2-1 | c.605_608del p.P202Rfs*14 | Frame Shift Del (DEL) | VAF 62/247 reads (25%) | called by mutect2, pindel, varscan2
- NOL6 | c.968G>A p.G323D | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); called by muse, mutect2
- NUDT12 | c.366C>G p.S122R | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- OLFML1 | c.815T>A p.L272Q | Missense Mutation (SNP) | VAF 54/257 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR10T2 | c.357G>A p.M119I | Missense Mutation (SNP) | VAF 89/192 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- OR1K1 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 82/261 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- OR1L8 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR1N2 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- OR4K2 | c.411T>A p.S137R | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- OR5H2 | c.333T>A p.F111L | Missense Mutation (SNP) | VAF 70/274 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ORC3 | c.114G>T p.E38D | Missense Mutation (SNP) | VAF 77/404 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OTOGL | c.4850T>A p.L1617* (on ENST00000547103; = p.L1608* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 16/380 reads (4%) | called by muse, mutect2
- PCDHAC2 | c.1003G>T p.V335L | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- PCDHGA1 | c.1249G>T p.G417W | Missense Mutation (SNP) | VAF 120/531 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- PCSK5 | c.3428A>C p.H1143P | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- PDZD11 | c.228+1G>A p.X76_splice | Splice Site (SNP) | VAF 59/281 reads (21%) | called by muse, mutect2, varscan2
- PFAS | c.3260G>T p.G1087V | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PFKP | c.707G>T p.W236L | Missense Mutation (SNP) | VAF 51/289 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PIK3CG | c.1480C>A p.Q494K | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT tolerated (0.93); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PLB1 | c.1965C>A p.H655Q | Missense Mutation (SNP) | VAF 65/408 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLS1 | c.519A>T p.E173D | Missense Mutation (SNP) | VAF 64/294 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- POU3F3 | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.636); called by muse, varscan2
- PRKCG | c.1832A>T p.H611L | Missense Mutation (SNP) | VAF 117/342 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- PRKD1 | c.325A>G p.T109A | Missense Mutation (SNP) | VAF 100/309 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRPS1L1 | c.610T>A p.C204S | Missense Mutation (SNP) | VAF 88/395 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPN13 | c.295-2A>T p.X99_splice | Splice Site (SNP) | VAF 40/213 reads (19%) | called by muse, mutect2, varscan2
- PTPRK | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 57/418 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- RAB8B | c.480+1G>T p.X160_splice | Splice Site (SNP) | VAF 90/389 reads (23%) | called by muse, mutect2, varscan2
- RAD50 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 78/332 reads (23%) | called by muse, mutect2, varscan2
- RIMS2 | c.3863C>A p.S1288* | Nonsense Mutation (SNP) | VAF 55/230 reads (24%) | called by muse, mutect2, varscan2
- ROBO1 | c.3882G>C p.Q1294H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- ROBO2 | c.459G>T p.E153D | Missense Mutation (SNP) | VAF 112/559 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- RPS3 | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2
- SACS | c.11127G>T p.E3709D | Missense Mutation (SNP) | VAF 61/337 reads (18%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- SAGE1 | c.2051G>T p.G684V | Missense Mutation (SNP) | VAF 69/273 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- SCG2 | c.646C>A p.R216S | Missense Mutation (SNP) | VAF 109/537 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SDE2 | c.1261G>T p.E421* | Nonsense Mutation (SNP) | VAF 360/984 reads (37%) | called by muse, mutect2, varscan2
- SEMA3F | c.1546G>T p.D516Y | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- SEMA6D | c.116G>T p.R39M | Missense Mutation (SNP) | VAF 62/252 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- SFRP1 | c.134C>A p.P45Q | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SH3D19 | c.1114G>T p.D372Y | Missense Mutation (SNP) | VAF 56/353 reads (16%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- SLC6A4 | c.477dup p.G160Rfs*70 | Frame Shift Ins (INS) | VAF 18/83 reads (22%) | called by mutect2, pindel, varscan2
- SLITRK3 | c.1037C>A p.S346Y | Missense Mutation (SNP) | VAF 103/444 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SNTG1 | c.1033C>A p.L345I | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SNX8 | c.540+1G>T p.X180_splice | Splice Site (SNP) | VAF 19/73 reads (26%) | called by muse, mutect2, varscan2
- SORCS1 | c.2557G>A p.D853N | Missense Mutation (SNP) | VAF 48/309 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SORCS2 | c.829G>T p.D277Y | Missense Mutation (SNP) | VAF 59/248 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SPAM1 | c.1387G>T p.V463F | Missense Mutation (SNP) | VAF 82/421 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- SPATA48 | c.268C>A p.P90T | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- SPCS3 | c.218-2A>G p.X73_splice | Splice Site (SNP) | VAF 33/157 reads (21%) | called by muse, mutect2, varscan2
- STARD8 | c.2707G>C p.G903R | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- SYAP1 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 84/349 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SYNE1 | c.12661T>G p.L4221V (on ENST00000367255 / NM_182961.4; = p.L4150V on NM_033071.3) | Missense Mutation (SNP) | VAF 64/300 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- SYNPO2 | c.2723_2724delinsT p.P908Lfs*55 | Frame Shift Del (DEL) | VAF 14/120 reads (12%) | called by pindel, varscan2*
- TBXT | c.1225G>T p.D409Y | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- TCP10L2 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 120/887 reads (14%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.3334G>T p.G1112* | Nonsense Mutation (SNP) | VAF 94/353 reads (27%) | called by muse, mutect2, varscan2
- TRPV1 | c.2431G>T p.E811* | Nonsense Mutation (SNP) | VAF 51/292 reads (17%) | called by muse, mutect2, varscan2
- TTK | c.1874A>T p.K625M | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2
- UBR4 | c.4349G>T p.C1450F | Missense Mutation (SNP) | VAF 50/308 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ULK1 | c.1666A>T p.S556C | Missense Mutation (SNP) | VAF 80/216 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- USH2A | c.3307T>A p.Y1103N | Missense Mutation (SNP) | VAF 159/632 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- WAS | c.1096G>T p.G366C | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2
- WDR45B | c.524A>T p.E175V | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- ZCCHC2 | c.2756C>A p.P919Q | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ZNF564 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- ZNF804A | c.615G>T p.Q205H | Missense Mutation (SNP) | VAF 87/311 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZNF804A | c.2391G>T p.R797S | Missense Mutation (SNP) | VAF 65/258 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ABCB7 | c.504C>G p.L168= (on ENST00000373394 / NM_001271696.3; = p.L169= on NM_004299.6) | Silent (SNP) | VAF 129/639 reads (20%) | called by muse, mutect2, varscan2
- ACER3 | c.12C>T p.A4= | Silent (SNP) | VAF 28/106 reads (26%) | called by muse, mutect2, varscan2
- APC | c.8184G>T p.V2728= | Silent (SNP) | VAF 97/334 reads (29%) | called by muse, mutect2, varscan2
- ASB12 | c.864C>A p.V288= | Silent (SNP) | VAF 75/394 reads (19%) | called by muse, mutect2, varscan2
- ATP2B3 | c.171C>T p.S57= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs1244211389; called by muse, mutect2, varscan2
- AZIN2 | c.894G>T p.L298= | Silent (SNP) | VAF 28/167 reads (17%) | called by muse, mutect2, varscan2
- C16orf82 | c.93A>T p.L31= | Silent (SNP) | VAF 42/170 reads (25%) | called by muse, mutect2, varscan2
- CAMTA2 | c.27T>G p.V9= | Silent (SNP) | VAF 74/377 reads (20%) | catalogued as rs775764816; called by muse, mutect2, varscan2
- CATSPER4 | c.957G>A p.Q319= | Silent (SNP) | VAF 29/105 reads (28%) | called by muse, mutect2, varscan2
- CEP290 | c.1386C>T p.V462= | Silent (SNP) | VAF 17/128 reads (13%) | catalogued as rs886038689, COSV58350048; ClinVar: likely benign; called by muse, mutect2, varscan2
- CHD9 | c.8601C>T p.S2867= (on ENST00000398510 / NM_001382353.1; = p.S2851= on NM_025134.7) | Silent (SNP) | VAF 20/327 reads (6%) | called by muse, mutect2
- COL18A1 | c.3468A>T p.A1156= (on ENST00000359759 / NM_130444.3; = p.A921= on NM_030582.4) | Silent (SNP) | VAF 20/114 reads (18%) | called by muse, varscan2
- CREB3L3 | c.72G>A p.E24= | Silent (SNP) | VAF 88/260 reads (34%) | called by muse, mutect2, varscan2
- CRNN | c.1353G>A p.V451= | Silent (SNP) | VAF 16/443 reads (4%) | catalogued as rs1349043462, COSV99663875; called by muse, mutect2
- CYP11B2 | c.1465T>C p.L489= | Silent (SNP) | VAF 52/263 reads (20%) | catalogued as rs139408911; called by muse, mutect2, varscan2
- DNAH9 | c.1344G>T p.V448= | Silent (SNP) | VAF 17/86 reads (20%) | called by muse, mutect2, varscan2
- FBXL7 | c.798C>A p.P266= | Silent (SNP) | VAF 29/131 reads (22%) | catalogued as COSV61645582; called by muse, mutect2, varscan2
- GFPT2 | c.111G>A p.S37= | Silent (SNP) | VAF 11/111 reads (10%) | catalogued as rs367562528; called by muse, mutect2, varscan2
- GFRA1 | c.1215C>T p.S405= | Silent (SNP) | VAF 36/651 reads (6%) | catalogued as COSV62604471, COSV62608579; called by muse, mutect2
- GLYATL3 | c.747C>T p.V249= | Silent (SNP) | VAF 24/107 reads (22%) | called by muse, varscan2
- GRIPAP1 | c.1864C>A p.R622= | Silent (SNP) | VAF 61/297 reads (21%) | called by muse, mutect2, varscan2
- HTR4 | c.21C>A p.L7= | Silent (SNP) | VAF 62/214 reads (29%) | called by muse, mutect2, varscan2
- IARS1 | c.177A>T p.I59= | Silent (SNP) | VAF 98/630 reads (16%) | called by muse, mutect2, varscan2
- ICE1 | c.5181G>T p.V1727= | Silent (SNP) | VAF 35/163 reads (21%) | called by muse, mutect2, varscan2
- ITPKB | c.2523A>G p.R841= | Silent (SNP) | VAF 59/339 reads (17%) | called by muse, mutect2, varscan2
- KRT40 | c.597G>T p.L199= | Silent (SNP) | VAF 21/139 reads (15%) | catalogued as COSV66696284; called by muse, mutect2, varscan2
- KRTAP15-1 | c.378C>T p.T126= | Silent (SNP) | VAF 7/61 reads (11%) | called by muse, varscan2
- LILRB4 | c.483C>A p.A161= | Silent (SNP) | VAF 57/222 reads (26%) | called by muse, mutect2, varscan2
- LMX1A | c.600C>A p.T200= | Silent (SNP) | VAF 148/396 reads (37%) | called by muse, mutect2, varscan2
- LRP1 | c.9921G>A p.L3307= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1030508654, COSV54529762; called by muse, mutect2, varscan2
- MFN1 | c.1632G>T p.V544= | Silent (SNP) | VAF 54/248 reads (22%) | called by muse, mutect2, varscan2
- MORC4 | c.1968C>A p.S656= | Silent (SNP) | VAF 62/227 reads (27%) | called by muse, mutect2, varscan2
- MSH6 | c.729C>G p.R243= | Silent (SNP) | VAF 32/341 reads (9%) | called by muse, mutect2
- MYBPC1 | c.1425C>T p.D475= (on ENST00000550270 / NM_206820.2; = p.D500= on NM_002465.4) | Silent (SNP) | VAF 114/596 reads (19%) | called by muse, mutect2, varscan2
- NAA11 | c.309C>T p.N103= | Silent (SNP) | VAF 49/247 reads (20%) | catalogued as rs764751693; called by muse, mutect2, varscan2
- NOS3 | c.1932C>A p.T644= | Silent (SNP) | VAF 37/150 reads (25%) | called by muse, mutect2, varscan2
- PCDHB10 | c.738G>T p.L246= | Silent (SNP) | VAF 50/188 reads (27%) | called by muse, mutect2, varscan2
- PDHA2 | c.645T>A p.P215= | Silent (SNP) | VAF 60/310 reads (19%) | called by muse, mutect2, varscan2
- PLA2G4C | c.57C>T p.A19= | Silent (SNP) | VAF 29/192 reads (15%) | catalogued as rs749663476, COSV62787591; called by muse, mutect2, varscan2
- PORCN | c.1056G>T p.L352= (on ENST00000326194 / NM_203475.3; = p.L341= on NM_022825.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 108/439 reads (25%) | called by muse, mutect2, varscan2
- PRKACG | c.1053T>C p.F351= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs1166056495; called by muse, mutect2
- PTBP3 | c.93C>T p.T31= | Silent (SNP) | VAF 51/472 reads (11%) | called by muse, mutect2, varscan2
- RIMS2 | c.978G>A p.E326= (on ENST00000666250 / NM_001348490.2; = p.E134= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 24/436 reads (6%) | called by muse, mutect2
- SCN8A | c.1374C>A p.V458= | Silent (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- SI | c.3543T>A p.P1181= | Silent (SNP) | VAF 155/630 reads (25%) | catalogued as COSV52285171; called by muse, mutect2, varscan2
- SLC12A6 | c.984T>C p.L328= (on ENST00000354181 / NM_001365088.1; = p.L277= on NM_005135.2) | Silent (SNP) | VAF 148/607 reads (24%) | catalogued as rs1566815460; called by muse, mutect2, varscan2
- SLC4A5 | c.3186C>A p.S1062= | Silent (SNP) | VAF 98/376 reads (26%) | called by muse, varscan2
- SLITRK2 | c.2466G>T p.L822= | Silent (SNP) | VAF 74/253 reads (29%) | called by muse, mutect2, varscan2
- SOGA3 | c.852C>A p.G284= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV64106265; called by muse, mutect2
- SUN5 | c.789C>A p.I263= | Silent (SNP) | VAF 21/184 reads (11%) | called by muse, mutect2, varscan2
- SYNE1 | c.16566C>T p.L5522= (on ENST00000367255 / NM_182961.4; = p.L5451= on NM_033071.3) | Silent (SNP) | VAF 113/566 reads (20%) | catalogued as rs1186908560; called by muse, mutect2, varscan2
- TBC1D8B | c.798C>A p.V266= | Silent (SNP) | VAF 41/150 reads (27%) | catalogued as COSV52179613; called by muse, mutect2, varscan2
- TCHHL1 | c.75G>A p.G25= | Silent (SNP) | VAF 18/228 reads (8%) | called by muse, mutect2
- TEX15 | c.2562C>T p.I854= (on ENST00000256246; = p.I1237= on NM_001350162.2) | Silent (SNP) | VAF 78/382 reads (20%) | called by muse, mutect2, varscan2
- TGM6 | c.786C>A p.L262= | Silent (SNP) | VAF 94/297 reads (32%) | called by muse, mutect2, varscan2
- UBTFL1 | c.672C>A p.P224= | Silent (SNP) | VAF 59/344 reads (17%) | called by muse, mutect2, varscan2
- UPP2 | c.513C>A p.P171= | Silent (SNP) | VAF 110/482 reads (23%) | called by muse, mutect2, varscan2
- USPL1 | c.1881A>T p.S627= | Silent (SNP) | VAF 52/353 reads (15%) | called by muse, mutect2, varscan2
- VCPIP1 | c.435G>T p.R145= | Silent (SNP) | VAF 38/134 reads (28%) | called by muse, mutect2, varscan2
- ZBTB33 | c.1209C>T p.G403= | Silent (SNP) | VAF 18/405 reads (4%) | catalogued as rs377285531; called by muse, mutect2
- AC024940.1 | n.2598A>G | RNA (SNP) | VAF 32/149 reads (21%) | called by muse, mutect2, varscan2
- AL355390.1 | n.529T>C | RNA (SNP) | VAF 32/136 reads (24%) | called by muse, mutect2, varscan2
- ALDH3A1 | c.395-138G>T | Intron (SNP) | VAF 60/319 reads (19%) | called by muse, mutect2, varscan2
- C5 | c.2563-2093A>G | Intron (SNP) | VAF 32/277 reads (12%) | called by muse, mutect2, varscan2
- ELOVL4 | c.-18C>T | 5'UTR (SNP) | VAF 18/238 reads (8%) | called by muse, mutect2
- FAM90A27P | n.383G>T | RNA (SNP) | VAF 75/251 reads (30%) | called by muse, mutect2, varscan2
- FMNL3 | c.*35G>A | 3'UTR (SNP) | VAF 6/56 reads (11%) | called by mutect2, varscan2
- GPR89B | chr1:147996601 G>C | 3'Flank (SNP) | VAF 233/656 reads (36%) | called by muse, mutect2, varscan2
- GSTO2 | c.468+6464G>A | Intron (SNP) | VAF 16/166 reads (10%) | called by muse, mutect2
- HEXA | c.805+37G>T | Intron (SNP) | VAF 65/271 reads (24%) | called by muse, mutect2, varscan2
- IQCG | c.-23G>T | 5'UTR (SNP) | VAF 31/170 reads (18%) | catalogued as rs1264909740; called by muse, mutect2, varscan2
- KRT12 | c.1095+30C>T | Intron (SNP) | VAF 31/319 reads (10%) | called by muse, mutect2
- KRT6A | c.912+25T>A | Intron (SNP) | VAF 53/418 reads (13%) | called by muse, mutect2, varscan2
- LINC01299 | n.2048G>A | RNA (SNP) | VAF 31/123 reads (25%) | called by muse, mutect2, varscan2
- LINC02656 | n.120T>G | RNA (SNP) | VAF 87/472 reads (18%) | called by muse, mutect2, varscan2
- MIR920 | n.21C>A | RNA (SNP) | VAF 108/520 reads (21%) | called by muse, mutect2, varscan2
- MMS22L | c.607-295G>T | Intron (SNP) | VAF 54/295 reads (18%) | catalogued as rs1439881989; called by muse, mutect2, varscan2
- MYH9 | c.2500-28A>T | Intron (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- OR2W5 | n.408C>T | RNA (SNP) | VAF 54/365 reads (15%) | called by muse, mutect2, varscan2
- PNCK | c.-2-80del | Intron (DEL) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- POLE | c.6658-317G>T | Intron (SNP) | VAF 38/135 reads (28%) | called by muse, mutect2, varscan2
- RAD51D | c.-73G>T | 5'UTR (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- REXO4 | c.572+87G>T | Intron (SNP) | VAF 67/212 reads (32%) | catalogued as rs782089798, COSV64241300; called by muse, mutect2, varscan2
- RN7SL319P | chr15:75782831 T>A | 5'Flank (SNP) | VAF 52/202 reads (26%) | called by muse, mutect2, varscan2
- SLC1A7 | c.1032-143T>C | Intron (SNP) | VAF 6/20 reads (30%) | catalogued as rs1369193215; called by muse, mutect2, varscan2
- SPEF2 | c.4448-3095del | Intron (DEL) | VAF 122/619 reads (20%) | called by mutect2, pindel, varscan2
- TIMM8A | c.132+179G>T | Intron (SNP) | VAF 46/220 reads (21%) | called by muse, mutect2, varscan2
- TMEM132E | chr17:34579232 C>T | 5'Flank (SNP) | VAF 11/42 reads (26%) | catalogued as rs377334422; called by muse, mutect2, varscan2
- TRPV3 | c.1503+43G>C | Intron (SNP) | VAF 22/90 reads (24%) | called by muse, varscan2
- TTC6 | chr14:37790737 G>T | 5'Flank (SNP) | VAF 147/409 reads (36%) | called by muse, mutect2, varscan2
- TTLL6 | c.998+1832G>T | Intron (SNP) | VAF 47/185 reads (25%) | called by muse, mutect2, varscan2
- VAPB | c.*5839A>C | 3'UTR (SNP) | VAF 196/733 reads (27%) | called by muse, mutect2, varscan2
- ZNF252P | n.245+4707A>T | Intron (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- ZNF770 | c.*1721C>T | 3'UTR (SNP) | VAF 22/311 reads (7%) | catalogued as COSV62544684; called by muse, mutect2
- ZNF81 | c.-98C>A | 5'UTR (SNP) | VAF 115/495 reads (23%) | called by muse, mutect2, varscan2
- ZNF849P | n.1055G>T | RNA (SNP) | VAF 74/236 reads (31%) | called by muse, varscan2
